Gene-level copy-number profile of tumor specimen ALCH-ADMM-TTP1-A from ALCHEMIST case ALCH-ADMM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.3 years (27,152 days).
Specimen ALCH-ADMM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f85a74ed-9cb9-4f55-969f-a0a062e62ca7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADMM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/738d6a9e-a316-4df5-ab67-e67c8d54edd6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 737; copy number 2: 16,889; copy number 3: 25,590; copy number 4: 8,092; copy number 5: 4,220; copy number 6: 1,044; copy number 7: 356; copy number 8: 224; copy number 9: 159; copy number 10: 170; copy number 11: 286; copy number 12: 97; copy number 13: 40; copy number 15: 22; copy number 16: 60; copy number 17: 94; copy number 18: 17; copy number 19: 2; copy number 23: 13; copy number 24: 148; copy number 30: 70.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,116,022–50,156,085, 1 gene (within-gene range 0–2): SEMA3F-AS1.
- chr3:50,362,613–50,504,244, 1 gene (within-gene range 0–1): CACNA2D2.
- chr3:50,419,781–50,419,899, 1 gene: RNA5SP131.
- chr9:61,190,003–61,666,386, 12 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr14:104,085,686–104,137,898, 4 genes: ASPG, MIR203A, MIR203B, AL359399.1.
- chr15:21,053,004–21,054,702, 1 gene: AC037471.1.
- chr15:21,148,334–21,167,357, 2 genes: AC126335.2, BMS1P16.
- chr15:25,172,635–25,225,284, 29 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr21:44,246,339–44,262,216, 2 genes (within-gene range 0–2): DNMT3L, DNMT3L-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,758 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,972,225–65,232,145, 10 genes, copy number 7: LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7.
- chr3:129,632,019–129,893,606, 5 genes, copy number 7: AC023162.1, TMCC1, RNY3P13, U6, AC083799.1.
- chr3:163,026,396–185,281,990, 344 genes, copy number 7–19 (broad region; genes not listed).
- chr4:67,701,209–68,080,952, 1 gene, copy number 11 (within-gene range 3–11): UBA6-AS1.
- chr4:67,718,996–72,569,221, 115 genes, copy number 8–11 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 8–12 (broad region; genes not listed).
- chr14:34,556,226–37,596,059, 78 genes, copy number 9–17 (within-gene range 2–17) (broad region; genes not listed).
- chr17:39,461,486–39,864,312, 17 genes, copy number 18: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr22:18,400,407–27,460,060, 509 genes, copy number 8–30 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 711. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
